Somatic mutation profile of tumor specimen 0DE3HI from CCDI case PBBNUZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.1 years (2,231 days).
Specimen 0DE3HI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e38b1cd1-240d-4e6d-8a6a-5d9e1134588b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE3GQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1283ac79-e97c-4003-97e0-3f17fece6039

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Nonsense Mutation 3, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 209/469 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 38/620 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARID1A | c.791C>A p.S264* | Nonsense Mutation (SNP) | VAF 102/364 reads (28%) | catalogued as COSV61381323; called by muse, varscan2
- ARID2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 78/248 reads (31%) | catalogued as COSV57595781; called by muse, mutect2, varscan2
- DDX3X | c.1232C>T p.S411F (on ENST00000399959; = p.S412F on NM_001356.5) | Missense Mutation (SNP) | VAF 199/211 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67863397; called by muse, mutect2, varscan2
- FRRS1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 109/734 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767465531, COSV54921096; called by muse, mutect2, varscan2
- KLHL8 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 24/789 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs1453793050; called by muse, mutect2
- SETDB2 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.839); catalogued as rs750928370; called by muse, mutect2, varscan2
- SLC15A4 | c.1495G>C p.G499R | Missense Mutation (SNP) | VAF 302/723 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57160888; called by muse, mutect2, varscan2
- SLCO2B1 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 303/668 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1282534010; called by muse, varscan2
- WNK1 | c.2527C>G p.Q843E | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as COSV60034975; called by muse, mutect2, varscan2
- ARID1A | c.4892dup p.P1632Afs*16 | Frame Shift Ins (INS) | VAF 31/292 reads (11%) | called by mutect2, varscan2
- KMT2D | c.12311_12312del p.Q4104Rfs*2 | Frame Shift Del (DEL) | VAF 35/273 reads (13%) | called by mutect2, varscan2
- PLPP4 | c.715G>T p.V239F | Missense Mutation (SNP) | VAF 219/508 reads (43%) | SIFT tolerated (0.62); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- UTP4 | c.967T>G p.Y323D | Missense Mutation (SNP) | VAF 28/801 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2
- ZBTB26 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 62/500 reads (12%) | called by muse, mutect2, varscan2
- EGFR | c.1932G>A p.P644= | Silent (SNP) | VAF 30/444 reads (7%) | catalogued as rs367909827, COSV99295655; called by muse, mutect2
- KLK8 | c.177C>T p.G59= | Silent (SNP) | VAF 27/552 reads (5%) | catalogued as rs770388543, COSV51593406, COSV51595347; called by muse, mutect2
- KRTAP13-1 | c.309A>T p.G103= | Silent (SNP) | VAF 44/709 reads (6%) | called by muse, mutect2
- NCAM1 | c.1188C>T p.T396= (on ENST00000316851 / NM_181351.5; = p.T386= on NM_000615.7) | Silent (SNP) | VAF 30/827 reads (4%) | catalogued as rs782777447, COSV100378554; called by muse, mutect2
- C21orf58 | c.310-57G>T | Intron (SNP) | VAF 67/143 reads (47%) | called by muse, mutect2, varscan2
- C4BPB | c.-59dup | 5'UTR (INS) | VAF 31/70 reads (44%) | catalogued as rs1369796554; called by mutect2, varscan2
